Somatic mutation profile of tumor specimen TCGA-DX-A3LU-01A (aliquot TCGA-DX-A3LU-01A-11D-A21Q-09) from TCGA case TCGA-DX-A3LU, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.0 years (21,915 days).
Specimen TCGA-DX-A3LU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dbb11dd-7535-4320-82d5-fe7fa625cbef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3LU-10A (Blood Derived Normal), aliquot TCGA-DX-A3LU-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/285496f5-222d-4d61-a1f1-d368b0ceb31d

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 19, Silent 9, Translation Start Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFB6 | c.77T>G p.L26W | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs958837244; called by muse, mutect2, varscan2
- CDKN1A | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs376481017, COSV55188894; called by muse, mutect2
- KIF4B | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs199820075, COSV101469192, COSV70526998; called by muse, mutect2, varscan2
- L1TD1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.431); catalogued as COSV63134154; called by muse, varscan2
- MYO5B | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV53229537; called by muse, mutect2, varscan2
- OR1J2 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs372492437, COSV58944775; called by muse, mutect2, varscan2
- PCDH17 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV100931678; called by muse, mutect2
- PDE1B | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs147900601; called by muse, mutect2, varscan2
- PRUNE2 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65049316; called by muse, mutect2, varscan2
- RSPRY1 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101071120; called by muse, mutect2, varscan2
- WNK2 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.32); catalogued as rs368902215, COSV104401297; called by muse, mutect2, varscan2
- YES1 | c.1243T>C p.F415L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58850781; called by muse, mutect2
- A2ML1 | c.735_773del p.Y246_V258del | In Frame Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- ARHGAP9 | c.1447G>A p.E483K (on ENST00000393797 / NM_001319850.2; = p.E464K on NM_032496.4) | Missense Mutation (SNP) | VAF 76/98 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BRCA2 | c.1899T>G p.N633K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2
- L1TD1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MEMO1 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PAK3 | c.774dup p.S259Ifs*6 (on ENST00000262836 / NM_001324328.2; = p.S244Ifs*6 on NM_002578.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- PREX2 | c.4520G>T p.G1507V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SF3B1 | c.2236T>G p.F746V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TUBAL3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF335 | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAJC16 | c.1614C>T p.P538= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- GCNT3 | c.657G>A p.P219= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs200140304; called by muse, mutect2, varscan2
- L1TD1 | c.342G>A p.G114= | Silent (SNP) | VAF 22/41 reads (54%) | called by muse, varscan2
- L1TD1 | c.1542G>A p.L514= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs747279476, COSV100776560; called by muse, varscan2
- PIP4K2C | c.795G>A p.K265= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- RELA | c.126C>T p.S42= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1277619988; called by muse, mutect2, varscan2
- RYR2 | c.696T>C p.D232= | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- THBS4 | c.828C>T p.P276= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs200566165, COSV63469766; called by muse, mutect2, varscan2
- TOX3 | c.1713G>A p.S571= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs768911675, COSV54864751; called by muse, mutect2, varscan2
